CCDI case PBBWVY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0af447ee-815f-46dd-82eb-788cc3b7e935

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Tumor cells, malignant: ICD-O-3 morphology code: 8001/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,290 days).

Biospecimens (3 samples)
- Sample 0DL1SX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL1T4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL1TM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
